CPTAC case C3L-08157 — Stomach — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c77a8be3-4c8b-4abd-a92c-73214c4cbed8

Demographics
Sex at birth: female; Race: white; Year of birth: 1951; Vital status: Alive; Country of birth: Ukraine.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Body of stomach; Age at diagnosis: 70.2 years (25,629 days); Year of diagnosis: 2021; AJCC staging edition: 8th; AJCC pathologic T: T4; AJCC pathologic N: N3b; AJCC pathologic stage: Stage IV; Tumor grade: G4; Residual disease: R0; Days to last known disease status: 999 days (2.7 years); Progression or recurrence: no; Days to last follow up: 999 days (2.7 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 6 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 16.

Follow-up (3 entries)
- Days to follow up: 442 days (1.2 years); Disease response: Complete Response; Karnofsky performance status: 70; ECOG performance status: 1.
- Days to follow up: 607 days (1.7 years); Disease response: Complete Response; Karnofsky performance status: 60; ECOG performance status: 2.
- Days to follow up: 999 days (2.7 years); Disease response: Complete Response; Karnofsky performance status: 60; ECOG performance status: 1.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-08157-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 510 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-08157-22: Section location: Body; Percent tumor nuclei: 50; Percent necrosis: 0.
- Sample C3L-08157-03: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 250 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-08157-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
